CCDI case PBCNFY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4020af3b-8c36-431a-9a24-67737e082a6d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,116 days).

Biospecimens (2 samples)
- Sample 0DWBCC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWBCN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
